Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L9, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L9-01A (Primary Tumor).

[page 1 of 2]
Procedure: most likely adrenalectomy

Gross description: missing

Reference Pathology only:

Diagnosis: adrenocortical carcinoma, KI67 5%

ICD-O-3

Tumor, Adrenal Cortical of.
unknown/uncertain behavior 8370/1

Site: Adrenal Gland, Cortex C74.0

JW 2/6/13

If case proves, we'll
request more pathology
then

4/11/13

Metastatic/Synchronous Primary Noted		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Tumor size(s)

Histologic diagnosis
ACC

Lymph Node Status

Pathologic nformation

Weiss score

Source: NCI Genomic Data Commons file 934ca9a5-8d02-4bfa-a2bb-760959f25577 (TCGA-OR-A5L9.09FD99AA-10FF-4E45-9B21-2B3F7D846758.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).